Gene-level copy-number profile of tumor specimen TCGA-58-8386-01A from TCGA case TCGA-58-8386, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.2 years (27,455 days).
Specimen TCGA-58-8386-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.628fabb9-7524-4902-aaea-5b4e13d6d3ce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-8386-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21205ab9-3d97-4df0-9442-a797cc98c968

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,568; copy number 2: 20,892; copy number 3: 19,094; copy number 4: 10,502; copy number 5: 3,625; copy number 6: 1,809; copy number 7: 963; copy number 8: 899; copy number 9: 271; copy number 10: 33; copy number 11: 39; copy number 12: 56; copy number 15: 26; copy number 16: 16; copy number 39: 8; copy number 49: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-58-8386-01A-11D-2292-01): tumor purity 0.35, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,325 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–42,191,523, 649 genes, copy number 8 (broad region; genes not listed).
- chr6:47,231,532–52,703,825, 76 genes, copy number 7 (broad region; genes not listed).
- chr6:54,943,167–56,394,094, 10 genes, copy number 8 (within-gene range 5–8): AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1.
- chr6:58,386,799–65,707,226, 39 genes, copy number 11 (within-gene range 2–20): AL603755.1, AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr6:123,216,339–123,685,323, 4 genes, copy number 12 (within-gene range 4–12): TRDN, TRDN-AS1, AL445259.1, AL133257.1.
- chr6:123,823,240–123,829,285, 1 gene, copy number 12: AL354936.1.
- chr7:54,185,071–56,051,604, 48 genes, copy number 15–49 (within-gene range 2–49): AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH.
- chr7:57,450,177–57,837,046, 24 genes, copy number 8–9: ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr7:91,940,862–117,874,139, 535 genes, copy number 7–16 (within-gene range 4–16) (broad region; genes not listed).
- chr9:126,589,594–127,980,989, 45 genes, copy number 8: AL161908.1, LMX1B, AL161908.2, AL161731.1, ZBTB43, ZBTB34, RALGPS1, ANGPTL2, AL450263.1, GARNL3, AL450263.2, AL445222.1, SLC2A8, ZNF79, RPL12, SNORA65, LRSAM1, Y_RNA, NIBAN2, STXBP1, AL162426.1, PTRH1, MIR3911, CFAP157, TTC16, TOR2A, SH2D3C, AL162586.2, CDK9, MIR3960, MIR2861, FPGS, ENG, AL162586.1, Y_RNA, RNA5SP296, AK1, AL157935.2, MIR4672, ST6GALNAC6, ST6GALNAC4, PIP5KL1, AL157935.1, DPM2, FAM102A.
- chr14:98,844,896–106,875,071, 525 genes, copy number 7 (broad region; genes not listed).
- chr16:11,555–523,011, 40 genes, copy number 8 (within-gene range 2–8): DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1, FAM234A, RGS11, Z69667.1, ARHGDIG, PDIA2, AXIN1, MRPL28, PGAP6, Z97634.1, NME4, DECR2, AL023881.1, RAB11FIP3, Y_RNA, AL049542.1.
- chr16:46,469,341–56,660,698, 252 genes, copy number 7 (broad region; genes not listed).
- chr16:58,733,910–59,199,395, 1 gene, copy number 8 (within-gene range 6–8): AC106793.1.
- chr16:58,847,715–60,656,649, 14 genes, copy number 8: AC092378.1, Metazoa_SRP, RPS27P27, AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP.
- chr19:28,065,267–31,466,431, 62 genes, copy number 8–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,213. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
